Somatic mutation profile of tumor specimen C3N-00518-01 (aliquot CPT0078000006_1) from CPTAC case C3N-00518, project CPTAC-3 (Pancreas — Ductal and Lobular Neoplasms). Sex at birth: male; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage IIB; Tumor grade: G3; Age at diagnosis: 69.7 years (25,462 days).
Specimen C3N-00518-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Pancreas; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e1ca40d1-ae5c-44f0-bd7b-1b713105d77e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-00518-31 (Blood Derived Normal), aliquot CPT0078080002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c37a400f-e4e7-4cdf-a268-55d47db2191d

The open-access MAF lists 33 somatic variants for this specimen: 26 protein-altering or splice-affecting, 5 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 22, Silent 5, Intron 2, Splice Site 1, Nonsense Mutation 1, Splice Region 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.183A>C p.Q61H | Missense Mutation (SNP) | VAF 51/401 reads (13%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.121); catalogued as rs17851045, COSV55498802, COSV55499223, COSV55811221; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ADCY5 | c.787C>T p.R263W | Missense Mutation (SNP) | VAF 10/168 reads (6%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.511); catalogued as COSV71901312; called by muse, mutect2
- ADCY8 | c.1621G>A p.E541K | Missense Mutation (SNP) | VAF 33/378 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as COSV53903634; called by muse, mutect2
- BCORL1 | c.1837del p.S613Lfs*35 | Frame Shift Del (DEL) | VAF 35/219 reads (16%) | catalogued as COSV54391338; called by mutect2, pindel, varscan2
- CLN3 | c.1045C>G p.L349V (on ENST00000360019 / NM_001286104.2; = p.L373V on NM_000086.2) | Missense Mutation (SNP) | VAF 74/872 reads (8%) | SIFT tolerated (0.2); PolyPhen benign (0.245); catalogued as rs752700529; ClinVar: uncertain significance; called by muse, mutect2
- DNAH17 | c.11050G>A p.V3684M | Missense Mutation (SNP) | VAF 17/188 reads (9%) | SIFT tolerated (0.13); PolyPhen benign (0.062); catalogued as rs772970929; called by muse, mutect2
- MSH2 | c.80C>T p.P27L | Missense Mutation (SNP) | VAF 62/1014 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.675); catalogued as rs750746034; ClinVar: uncertain significance; called by muse, mutect2
- MYO1A | c.1701C>G p.F567L | Missense Mutation (SNP) | VAF 58/1056 reads (5%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.992); catalogued as rs1362765973, COSV100271499; called by muse, mutect2
- PCDHB9 | c.2156C>T p.A719V | Missense Mutation (SNP) | VAF 51/773 reads (7%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.65); catalogued as COSV53376611; called by muse, mutect2
- PDE10A | c.1425C>A p.F475L | Missense Mutation (SNP) | VAF 29/321 reads (9%) | SIFT tolerated (0.15); PolyPhen benign (0.038); catalogued as rs773851683; called by muse, mutect2
- PPP2R1B | c.256G>A p.G86R | Missense Mutation (SNP) | VAF 41/571 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.841); catalogued as rs782540147; called by muse, mutect2
- SMAD4 | c.212G>A p.C71Y | Missense Mutation (SNP) | VAF 44/423 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100747627; called by muse, mutect2, varscan2
- SMTN | c.2333G>A p.G778D | Missense Mutation (SNP) | VAF 20/318 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.661); catalogued as COSV60784259; called by muse, mutect2
- UGT2B28 | c.232C>G p.P78A | Missense Mutation (SNP) | VAF 34/346 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.517); catalogued as COSV59433264; called by muse, mutect2
- ETS2 | c.632A>C p.N211T | Missense Mutation (SNP) | VAF 84/981 reads (9%) | SIFT tolerated (0.7); PolyPhen benign (0.014); called by muse, mutect2
- FBXO40 | c.151G>A p.E51K | Missense Mutation (SNP) | VAF 37/439 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.592); called by muse, mutect2
- HSF1 | c.356T>G p.V119G | Missense Mutation (SNP) | VAF 38/411 reads (9%) | SIFT tolerated (0.07); PolyPhen probably damaging (1); called by muse, mutect2
- OR14J1 | c.445G>T p.A149S | Missense Mutation (SNP) | VAF 40/450 reads (9%) | SIFT tolerated (1); PolyPhen benign (0.022); called by muse, mutect2
- PFAS | c.931C>T p.H311Y | Missense Mutation (SNP) | VAF 28/263 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PLCB3 | c.3422A>G p.E1141G | Missense Mutation (SNP) | VAF 38/518 reads (7%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.99); called by muse, mutect2
- PNPT1 | c.1441+1G>C p.X481_splice | Splice Site (SNP) | VAF 12/190 reads (6%) | called by muse, mutect2
- PPP1R26 | c.3130T>C p.S1044P | Missense Mutation (SNP) | VAF 6/88 reads (7%) | SIFT tolerated (0.23); PolyPhen benign (0.001); called by muse, mutect2
- RBM10 | c.2430G>A p.E810= | Splice Region (SNP) | VAF 89/589 reads (15%) | called by muse, mutect2, varscan2
- RFTN1 | c.1666A>C p.N556H | Missense Mutation (SNP) | VAF 57/778 reads (7%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0); called by muse, mutect2
- SIPA1L1 | c.2436C>A p.Y812* | Nonsense Mutation (SNP) | VAF 18/497 reads (4%) | called by muse, mutect2
- SMIM24 | c.278A>C p.E93A | Missense Mutation (SNP) | VAF 14/406 reads (3%) | SIFT tolerated (0.36); PolyPhen benign (0.005); called by muse, mutect2
- ACOXL | c.1425C>T p.H475= (on ENST00000389811 / NM_001371254.1; = p.H445= on NM_001142807.4) | Silent (SNP) | VAF 34/508 reads (7%) | catalogued as rs757294119; called by muse, mutect2
- MINPP1 | c.591G>T p.G197= | Silent (SNP) | VAF 44/344 reads (13%) | catalogued as rs910432787; called by muse, mutect2, varscan2
- PCNT | c.366C>T p.V122= | Silent (SNP) | VAF 80/918 reads (9%) | catalogued as CD080887; called by muse, mutect2
- RIOX1 | c.921T>A p.T307= | Silent (SNP) | VAF 38/402 reads (9%) | called by muse, mutect2
- TNRC6A | c.4431A>T p.P1477= | Silent (SNP) | VAF 116/1133 reads (10%) | called by muse, mutect2, varscan2
- BTG4 | c.510+106C>T | Intron (SNP) | VAF 9/73 reads (12%) | called by muse, mutect2
- CCDC196 | c.716-1815A>G | Intron (SNP) | VAF 38/522 reads (7%) | called by muse, mutect2
